Somatic mutation profile of tumor specimen TCGA-KL-8324-01A (aliquot TCGA-KL-8324-01A-11D-2310-10) from TCGA case TCGA-KL-8324, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.5 years (24,650 days).
Specimen TCGA-KL-8324-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4d74d5-71d4-4cfd-8745-e16471caf256.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8324-11A (Solid Tissue Normal), aliquot TCGA-KL-8324-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cf3f560-d8c5-4708-a8b1-983f5ecc68dd

The open-access MAF lists 29 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 25, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGBL1 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs753190553, COSV101222636; called by muse, mutect2
- ANKRD11 | c.3602T>A p.V1201D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV99968929; called by muse, mutect2, varscan2
- ATF7IP | c.1652T>G p.F551C | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.673); catalogued as rs867703102, COSV99661457; called by muse, mutect2
- B3GALNT1 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100251975; called by muse, mutect2
- EHBP1L1 | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV100499805; called by muse, mutect2, varscan2
- ELAPOR1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs143784237; called by muse, varscan2
- FAM98B | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV67022259; called by muse, mutect2, varscan2
- FOXJ2 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99368378; called by muse, mutect2
- HECW2 | c.3580G>A p.E1194K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs768772775, COSV53653263; called by muse, mutect2, varscan2
- IFNLR1 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100552068; called by muse, mutect2, varscan2
- ITGAM | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99792167; called by muse, mutect2, varscan2
- KIAA1755 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs753912139, COSV99641812; called by muse, mutect2
- KIF5B | c.1314A>T p.E438D | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV100191727; called by muse, mutect2
- NLRP8 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372844411, COSV99406108; called by mutect2, varscan2
- NPHS1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs149649169; called by muse, mutect2, varscan2
- PIAS2 | c.1262A>T p.D421V | Missense Mutation (SNP) | VAF 156/344 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100245175; called by muse, mutect2, varscan2
- POLR2A | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs201628232, COSV59496167; called by muse, mutect2, varscan2
- PRDM8 | c.1971G>C p.L657F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100325067; called by muse, mutect2, varscan2
- PRKCG | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1235252410, COSV54727061; called by muse, mutect2, varscan2
- RCN3 | c.101del p.V34Gfs*7 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as COSV54543424; called by mutect2, pindel, varscan2
- SLC9C2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as rs775523749, COSV100876690, COSV100876800; called by muse, mutect2, varscan2
- SYNE1 | c.12889G>C p.D4297H (on ENST00000367255 / NM_182961.4; = p.D4226H on NM_033071.3) | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV99559376; called by muse, mutect2, varscan2
- TMEM184B | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1212536479, COSV100725944; called by muse, mutect2, varscan2
- TMEM61 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.093); catalogued as COSV100987733; called by muse, mutect2
- PCDHB9 | c.2110T>C p.S704P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- FAT1 | c.10314C>A p.P3438= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV71674185, COSV71674899; called by muse, varscan2
- FSIP2 | c.20469A>G p.L6823= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV100554730; called by muse, mutect2, varscan2
- KCNS2 | c.153G>A p.S51= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs772162327, COSV54638464; called by muse, mutect2, varscan2
